Somatic mutation profile of tumor specimen C3N-03756-01 (aliquot CPT0248110006) from CPTAC case C3N-03756, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 67.0 years (24,462 days).
Specimen C3N-03756-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea7e2829-fe40-492e-a0fb-d934edf34b67.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03756-31 (Blood Derived Normal), aliquot CPT0248150002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ff3b95b-ead5-423d-912c-b8f58d2a2aca

The open-access MAF lists 102 somatic variants for this specimen: 61 protein-altering or splice-affecting, 25 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 25, Intron 9, 3'UTR 4, Splice Site 3, Splice Region 1, Frame Shift Del 1, Nonsense Mutation 1, 3'Flank 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3R1 | c.1746-7_1758del p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (DEL) | VAF 64/192 reads (33%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADAMTS3 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.541); catalogued as rs780846847; called by muse, mutect2, varscan2
- ALDH8A1 | c.119C>A p.P40Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55641977; called by muse, varscan2
- ALDH8A1 | c.53T>C p.F18S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV55642186; called by muse, varscan2
- CCBE1 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 192/550 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV67951279; called by muse, mutect2, varscan2
- CFAP57 | c.2323C>T p.R775W | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs187149881; called by muse, varscan2
- CHPF | c.1241T>C p.L414P | Missense Mutation (SNP) | VAF 96/231 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99705067; called by muse, mutect2, varscan2
- CHST5 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.133); catalogued as COSV100292014, COSV60339764; called by muse, mutect2
- CYP27B1 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 2107/5055 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as rs866796725, COSV56986121; called by muse, mutect2, varscan2
- CYP27B1 | c.37C>T p.H13Y | Missense Mutation (SNP) | VAF 374/7890 reads (5%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.036); catalogued as COSV57349703; called by muse, mutect2
- CYSLTR2 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 87/373 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs201503697; called by muse, mutect2, varscan2
- DST | c.5789T>C p.I1930T | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.053); catalogued as rs769164207; called by muse, mutect2, varscan2
- IGSF9 | c.2284C>T p.R762W (on ENST00000368094 / NM_001135050.2; = p.R746W on NM_020789.4) | Missense Mutation (SNP) | VAF 138/290 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs375167066; called by muse, mutect2, varscan2
- KCP | c.2615G>A p.R872Q (on ENST00000620378; = p.R932Q on NM_001366122.1) | Missense Mutation (SNP) | VAF 107/499 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.213); catalogued as rs1053570128; called by muse, mutect2, varscan2
- KRT38 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs371518902; called by muse, mutect2, varscan2
- MAGEB16 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.075); catalogued as rs769654089, COSV101303301, COSV67874292; called by muse, mutect2, varscan2
- MAOA | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 144/166 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs779805250, COSV58643180; called by muse, mutect2, varscan2
- RBAK | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 66/199 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs142273025; called by muse, mutect2, varscan2
- RYR1 | c.11023G>A p.D3675N | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs145026307; called by muse, mutect2, varscan2
- TCHH | c.3776G>A p.R1259H | Missense Mutation (SNP) | VAF 179/327 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as rs1458354783; called by muse, mutect2, varscan2
- TMEM132D | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs759524697, COSV70609077; called by muse, mutect2, varscan2
- TRPM2 | c.2638G>A p.V880M | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as rs774923547, COSV55965898, COSV55967710; called by muse, mutect2, varscan2
- TUSC3 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 145/338 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs554205458, COSV65879924; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZMYND11 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.804); catalogued as rs1365467790; called by muse, mutect2, varscan2
- ZNF143 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 60/150 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1265421932; called by muse, mutect2, varscan2
- ABCA6 | c.2024A>T p.E675V | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRB1 | c.1889C>T p.T630I | Missense Mutation (SNP) | VAF 93/245 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1I | c.633T>A p.N211K | Missense Mutation (SNP) | VAF 168/555 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CACNG3 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 90/216 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR1 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 86/336 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- DPP8 | c.1504+1G>A p.X502_splice (on ENST00000341861 / NM_001320875.2; = p.X486_splice on NM_017743.6) | Splice Site (SNP) | VAF 66/145 reads (46%) | called by muse, mutect2, varscan2
- ENDOD1 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EPG5 | c.2179A>G p.M727V | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- EVI5L | c.2230G>A p.V744M | Missense Mutation (SNP) | VAF 157/383 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- FAM118B | c.211del p.A71Pfs*12 | Frame Shift Del (DEL) | VAF 45/148 reads (30%) | called by mutect2, pindel, varscan2
- GJA1 | c.209T>C p.F70S | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); called by muse, mutect2
- GRIP1 | c.1522G>A p.A508T (on ENST00000359742 / NM_001379345.1; = p.A456T on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2
- HTT | c.4066C>A p.H1356N | Missense Mutation (SNP) | VAF 20/481 reads (4%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); called by muse, mutect2
- JAG2 | c.3298G>C p.V1100L | Missense Mutation (SNP) | VAF 236/596 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- KCNB2 | c.898G>A p.V300I | Missense Mutation (SNP) | VAF 86/194 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- LRCH1 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 119/265 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- MAPK15 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MME | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- MPZL1 | c.311A>G p.K104R | Missense Mutation (SNP) | VAF 97/279 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- MUC19 | c.583G>A p.G195S | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.934); called by muse, mutect2
- MYO6 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NCF2 | c.326A>T p.Y109F | Missense Mutation (SNP) | VAF 135/421 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- NUP210 | c.2733G>A p.Q911= | Splice Region (SNP) | VAF 61/154 reads (40%) | called by muse, mutect2, varscan2
- PPFIA1 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PTGR2 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 38/123 reads (31%) | called by muse, mutect2, varscan2
- PTTG1 | c.571G>T p.V191F | Missense Mutation (SNP) | VAF 75/175 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- QRICH1 | c.2135A>G p.K712R | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- RELN | c.9997G>T p.V3333F | Missense Mutation (SNP) | VAF 80/484 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- SDC4 | c.101A>G p.E34G | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- SIDT1 | c.1250_1263+5del p.X417_splice | Splice Site (DEL) | VAF 42/120 reads (35%) | called by mutect2, pindel
- SLC9A2 | c.1974C>A p.H658Q | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SON | c.6301A>G p.T2101A | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- TRPC4 | c.773A>G p.Q258R | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- TRRAP | c.10135G>A p.G3379R (on ENST00000359863 / NM_001244580.1; = p.G3350R on NM_003496.3) | Missense Mutation (SNP) | VAF 161/830 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- WDR3 | c.2378A>G p.N793S | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- WNK2 | c.4441C>G p.L1481V (on ENST00000297954 / NM_001282394.1; = p.L1444V on NM_006648.3) | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- ADGRA3 | c.72G>A p.L24= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, varscan2
- AGAP2 | c.1044C>T p.I348= | Silent (SNP) | VAF 709/5350 reads (13%) | called by mutect2, varscan2
- ATF3 | c.465C>T p.V155= | Silent (SNP) | VAF 127/246 reads (52%) | called by muse, mutect2, varscan2
- GOLGA1 | c.780C>T p.A260= | Silent (SNP) | VAF 67/180 reads (37%) | catalogued as COSV65230483; called by muse, mutect2, varscan2
- IFT27 | c.192C>T p.D64= (on ENST00000433985 / NM_001363003.2; = p.D63= on NM_006860.5) | Silent (SNP) | VAF 37/301 reads (12%) | called by muse, mutect2, varscan2
- IGFN1 | c.2907C>T p.P969= (on ENST00000295591 / NM_001367841.1; = p.P3426= on NM_001164586.2) | Silent (SNP) | VAF 56/110 reads (51%) | catalogued as rs574224409, COSV99813691; called by muse, mutect2, varscan2
- LTBP2 | c.1518C>T p.S506= | Silent (SNP) | VAF 77/199 reads (39%) | catalogued as rs766749435; called by muse, mutect2, varscan2
- MROH2B | c.2847G>A p.A949= | Silent (SNP) | VAF 70/170 reads (41%) | catalogued as rs371233888; called by muse, mutect2, varscan2
- NSMF | c.1059C>T p.S353= (on ENST00000371475 / NM_001130969.3; = p.S351= on NM_015537.4) | Silent (SNP) | VAF 138/312 reads (44%) | catalogued as rs1320491501; called by muse, mutect2, varscan2
- PCDHGA1 | c.2094C>T p.A698= | Silent (SNP) | VAF 94/487 reads (19%) | called by muse, mutect2, varscan2
- PRKCB | c.429C>T p.C143= | Silent (SNP) | VAF 62/132 reads (47%) | catalogued as rs760934314; called by muse, mutect2, varscan2
- PRSS38 | c.297G>A p.A99= | Silent (SNP) | VAF 89/165 reads (54%) | catalogued as rs200682477, COSV64540654; called by muse, mutect2, varscan2
- PTGS1 | c.1638G>A p.P546= | Silent (SNP) | VAF 108/262 reads (41%) | catalogued as rs1218265301, COSV56291812; called by muse, mutect2, varscan2
- PTPRQ | c.2391G>A p.S797= (on ENST00000616559; = p.S755= on NM_001145026.2) | Silent (SNP) | VAF 44/181 reads (24%) | catalogued as rs927689913, COSV99884925; called by muse, mutect2, varscan2
- PXDN | c.2529C>T p.D843= | Silent (SNP) | VAF 141/265 reads (53%) | catalogued as rs949156715; called by muse, mutect2, varscan2
- RTEL1 | c.687G>A p.L229= | Silent (SNP) | VAF 102/234 reads (44%) | called by muse, mutect2, varscan2
- SEMA5A | c.2952C>T p.L984= | Silent (SNP) | VAF 166/398 reads (42%) | called by muse, mutect2, varscan2
- SYT10 | c.225C>T p.V75= | Silent (SNP) | VAF 12/176 reads (7%) | called by muse, mutect2
- SYT13 | c.1056C>A p.I352= | Silent (SNP) | VAF 49/220 reads (22%) | called by muse, mutect2, varscan2
- TMEM236 | c.903C>T p.F301= | Silent (SNP) | VAF 303/705 reads (43%) | called by muse, mutect2, varscan2
- TRPM5 | c.969C>T p.S323= | Silent (SNP) | VAF 82/212 reads (39%) | catalogued as rs574197371; called by muse, varscan2
- UGT2B7 | c.762C>T p.D254= | Silent (SNP) | VAF 62/146 reads (42%) | catalogued as rs762185740; called by muse, mutect2, varscan2
- WDR46 | c.1218C>T p.H406= | Silent (SNP) | VAF 44/262 reads (17%) | called by muse, mutect2, varscan2
- ZNF549 | c.444A>G p.Q148= (on ENST00000376233 / NM_001199295.2; = p.Q135= on NM_153263.2) | Silent (SNP) | VAF 46/178 reads (26%) | called by muse, mutect2, varscan2
- ZNF716 | c.486C>T p.C162= | Silent (SNP) | VAF 14/276 reads (5%) | catalogued as rs368813044, COSV70783393; called by muse, mutect2
- ASB18 | c.205+4567C>T | Intron (SNP) | VAF 70/181 reads (39%) | called by muse, mutect2, varscan2
- C2orf72 | c.*11C>T | 3'UTR (SNP) | VAF 151/356 reads (42%) | called by muse, mutect2, varscan2
- CASK | c.1156-33_1156-30del | Intron (DEL) | VAF 73/89 reads (82%) | catalogued as rs773530254; called by mutect2, pindel, varscan2
- COL24A1 | c.4782+989C>G | Intron (SNP) | VAF 19/302 reads (6%) | called by muse, mutect2
- CSF2RB | c.-17C>A | 5'UTR (SNP) | VAF 298/497 reads (60%) | called by muse, mutect2, varscan2
- CYP27B1 | c.963+63C>G | Intron (SNP) | VAF 2170/6243 reads (35%) | called by muse, mutect2, varscan2
- CYP27B1 | c.387-69C>T | Intron (SNP) | VAF 1766/4922 reads (36%) | called by muse, mutect2, varscan2
- DNASE1 | c.802-18G>A | Intron (SNP) | VAF 30/684 reads (4%) | catalogued as rs917681330; called by muse, mutect2
- FAM20A | c.1219+253G>A | Intron (SNP) | VAF 12/219 reads (5%) | called by muse, mutect2
- GDAP1 | c.*240A>G | 3'UTR (SNP) | VAF 101/292 reads (35%) | called by muse, mutect2, varscan2
- NGRN | chr15:90275215 G>A | 3'Flank (SNP) | VAF 10/100 reads (10%) | called by muse, mutect2
- PDIA4 | c.88+432G>A | Intron (SNP) | VAF 96/412 reads (23%) | catalogued as rs1290498390; called by muse, mutect2, varscan2
- PRDM5 | c.744-49G>A | Intron (SNP) | VAF 109/244 reads (45%) | called by muse, mutect2, varscan2
- SARAF | c.*4A>G | 3'UTR (SNP) | VAF 70/160 reads (44%) | catalogued as rs1336512113; called by muse, mutect2, varscan2
- SERPINB13 | chr18:63587104 A>T | 5'Flank (SNP) | VAF 6/116 reads (5%) | called by muse, mutect2
- SLC17A2 | c.*78del | 3'UTR (DEL) | VAF 69/229 reads (30%) | called by mutect2, pindel, varscan2
